Gene-level copy-number profile of tumor specimen ALCH-B36C-TTP1-A from ALCHEMIST case ALCH-B36C, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.3 years (24,582 days).
Specimen ALCH-B36C-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5a86e8fc-d44b-4aea-b14f-464be35f531b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B36C-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,259 have no estimate.
https://portal.gdc.cancer.gov/files/c8ce7cd3-d87f-4c52-aee4-8be0c755f000

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 103; copy number 1: 6,991; copy number 2: 47,267; copy number 3: 2,896; copy number 4: 418; copy number 5: 513; copy number 6: 136; copy number 7: 20; copy number 8: 7; copy number 9: 5; copy number 10: 2; copy number 11: 1; copy number 14: 3; copy number 20: 1; copy number 38: 1.

Homozygous deletions (total copy number 0; autosomes only): 103 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,169,357–1,170,343, 1 gene: AL390719.2.
- chr1:1,211,340–1,214,153, 1 gene: TNFRSF4.
- chr1:2,811,850–2,817,767, 3 genes: AL592464.2, AL592464.3, AL592464.1.
- chr1:12,926,162–13,179,464, 14 genes (within-gene range 0–2): PRAMEF29P, PRAMEF6, PRAMEF28P, PRAMEF27, HNRNPCL3, PRAMEF25, PRAMEF34P, PRAMEF35P, HNRNPCL2, PRAMEF36P, AC245056.1, PRAMEF26, HNRNPCL4, PRAMEF9.
- chr1:13,245,863–13,248,652, 1 gene: PRAMEF31P.
- chr1:13,279,125–13,392,629, 8 genes: RNU6-771P, PRAMEF8, PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19, PRAMEF17.
- chr1:20,482,391–20,486,210, 1 gene: CAMK2N1.
- chr1:20,552,573–20,555,020, 1 gene: FAM43B.
- chr1:243,005,845–243,007,468, 1 gene: AL606534.3.
- chr2:236,165,236–236,168,386, 1 gene (within-gene range 0–1): GBX2.
- chr3:9,498,361–9,553,822, 1 gene: LHFPL4.
- chr3:11,859,674–11,912,313, 5 genes: FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1.
- chr3:13,479,724–13,506,424, 1 gene (within-gene range 0–1): HDAC11.
- chr3:14,489,107–14,556,075, 2 genes (within-gene range 0–1): GRIP2, RNU6-905P.
- chr3:38,548,057–38,649,687, 1 gene: SCN5A.
- chr3:46,719,583–46,736,429, 1 gene (within-gene range 0–1): PRSS46P.
- chr3:48,644,194–48,644,280, 1 gene (within-gene range 0–1): MIR4793.
- chr3:49,887,002–49,903,873, 2 genes (within-gene range 0–4): MST1R, AC105935.2.
- chr3:50,419,781–50,571,027, 2 genes (within-gene range 0–2): RNA5SP131, C3orf18.
- chr3:51,391,285–51,500,002, 2 genes: RBM15B, DCAF1.
- chr3:52,812,962–52,835,729, 3 genes (within-gene range 0–2): ITIH4, AC006254.1, ITIH4-AS1.
- chr3:75,384,059–75,538,029, 7 genes (within-gene range 0–1): AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2.
- chr3:75,540,049–75,590,649, 3 genes (within-gene range 0–1): AC133041.1, RPS3AP15, AC108724.1.
- chr5:179,377,505–179,385,992, 3 genes: AC109479.3, AC109479.1, AC109479.2.
- chr9:136,796,338–136,810,042, 2 genes (within-gene range 0–4): CCDC183, AL355987.4.
- chr10:129,768,844–129,973,053, 6 genes: AL157832.1, EBF3, AL354950.2, MIR4297, AL354950.1, AL354950.3.
- chr14:94,726,288–94,727,175, 1 gene: RPSAP4.
- chr17:909,632–911,212, 1 gene (within-gene range 0–1): AC087392.1.
- chr17:2,712,309–2,749,504, 5 genes (within-gene range 0–1): AC005696.1, AC005696.4, CCDC92B, MIR1253, hsa-mir-1253.
- chr17:3,126,584–3,127,581, 1 gene: OR1G1.
- chr17:10,320,392–10,341,458, 1 gene (within-gene range 0–1): AC005291.1.
- chr17:12,990,149–13,018,065, 2 genes (within-gene range 0–1): AC005277.1, ELAC2.
- chr17:16,342,534–16,353,656, 1 gene (within-gene range 0–1): CENPV.
- chr17:16,414,524–16,416,689, 1 gene (within-gene range 0–2): AC093484.2.
- chr18:78,795,612–78,796,672, 1 gene: AC044873.1.
- chr20:43,222,206–43,231,260, 2 genes: RN7SL666P, PPIAP21.
- chr20:51,831,797–51,862,912, 1 gene: LINC01429.
- chr20:52,051,663–52,204,308, 3 genes: ZFP64, AL109984.1, ERP29P1.
- chr20:56,730,397–56,731,460, 1 gene: AL133232.1.
- chr20:59,352,195–59,364,773, 2 genes: AL035250.1, AL035250.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 689 genes in 73 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,508,537–2,547,460, 3 genes, copy number 6: PANK4, HES5, AL139246.5.
- chr1:2,635,976–2,801,717, 3 genes, copy number 8 (within-gene range 2–8): TTC34, AC242022.2, AC242022.1.
- chr3:140,619,694–140,980,995, 6 genes, copy number 5: AC048346.1, TRIM42, AC121333.1, RPL23AP41, SLC25A36, AC108727.1.
- chr3:141,324,213–141,615,344, 6 genes, copy number 6–7 (within-gene range 4–7): ZBTB38, AC010184.1, KRT18P35, RASA2, RASA2-IT1, YWHAQP6.
- chr3:142,157,527–142,807,888, 14 genes, copy number 5 (within-gene range 4–6): GK5, XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1, RN7SKP25, AC072028.1, TRPC1.
- chr3:142,912,116–144,445,844, 21 genes, copy number 5–6: AC021074.3, PAQR9, AC021074.2, PAQR9-AS1, U2SURP, AC026304.1, AC018450.2, CHST2, AC018450.1, PBX2P1, SLC9A9, AC131210.1, SLC9A9-AS1, SLC9A9-AS2, GAPDHP47, ST13P15, AC073358.1, AC107421.1, DIPK2A, RNA5SP144, AC011592.1.
- chr3:145,684,572–146,495,991, 12 genes, copy number 5–6: GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2.
- chr3:146,515,180–146,606,216, 4 genes, copy number 5–6: PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1.
- chr3:147,590,996–148,591,927, 12 genes, copy number 5–6: NPM1P28, AC092925.1, AC092958.1, AC092958.4, LINC02032, AC092958.3, AC092958.2, AC025566.1, HNRNPA1P20, LINC02045, LINC02046, AC069410.1.
- chr3:148,985,868–149,503,394, 21 genes, copy number 5–6: UBQLN4P1, GYG1, HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5.
- chr3:149,738,472–153,200,017, 70 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:153,376,831–154,677,119, 19 genes, copy number 5–7: AC078788.2, LINC02006, LINC02877, RNU6-901P, Y_RNA, AC068985.1, U8, RPL21P42, ARHGEF26-AS1, ARHGEF26, DHX36, AC134026.1, AC134026.2, GPR149, DDX50P2, AC092994.1, SYPL1P1, DYNLL1P5, RPL9P15.
- chr3:155,024,124–155,309,807, 6 genes, copy number 5: MME, MME-AS1, LINC01487, STRIT1, AC104831.1, PABPC1P10.
- chr3:156,539,553–157,533,619, 23 genes, copy number 5–8 (within-gene range 4–8): SSR3, TIPARP-AS1, TIPARP, METTL15P1, LINC00886, PA2G4P4, LEKR1, KLF3P2, AC117392.1, RN7SKP177, LINC00880, LINC02029, LINC00881, CCNL1, Y_RNA, KRT18P34, AC104411.1, RNA5SP146, AC092944.1, AC092944.2, AC092944.3, VEPH1, PTX3.
- chr3:157,814,822–158,841,960, 22 genes, copy number 5–6: AC079943.2, RN7SKP46, AC079943.1, SHOX2, RSRC1, AC074276.1, AC074276.2, AC106707.2, AC106707.1, MLF1, MTAPP1, AC025033.1, GFM1, LXN, AC080013.3, RARRES1, MFSD1, AC080013.1, RPL35AP9, AC080013.2, AC080013.4, GPR79.
- chr3:159,711,852–159,897,360, 5 genes, copy number 5 (within-gene range 5–6): AC092943.2, AC092943.1, IQCJ-SCHIP1-AS1, RNU2-31P, SCHIP1.
- chr3:160,225,496–161,821,908, 29 genes, copy number 5–6: C3orf80, AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC131211.1.
- chr3:167,683,298–168,830,599, 12 genes, copy number 5–7 (within-gene range 4–7): PDCD10, HMGN1P8, SERPINI1, AC079822.1, LRRC77P, AC026353.1, MEMO1P3, AC128713.1, HMGN2P26, GOLIM4, AC069243.1, EGFEM1P.
- chr3:168,551,854–172,831,229, 88 genes, copy number 5–7 (broad region; genes not listed).
- chr3:173,396,284–175,810,548, 9 genes, copy number 5 (within-gene range 4–6): NLGN1, AC092967.1, NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1, NAALADL2, RN7SKP40, EEF1B2P8.
- chr3:175,234,861–175,776,333, 9 genes, copy number 5 (within-gene range 5–6): NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P, AC119744.1, UBE2V1P2, RNU6-1317P, NAALADL2-AS1.
- chr3:176,415,439–177,228,000, 8 genes, copy number 5–6: LINC01208, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P.
- chr3:177,337,628–179,240,093, 23 genes, copy number 5–7 (within-gene range 4–8): AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4, LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1.
- chr3:179,653,040–180,037,053, 6 genes, copy number 5: USP13, PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2, AC092939.1.
- chr3:181,952,343–182,655,880, 10 genes, copy number 5–6: LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031.
- chr3:182,739,669–182,985,953, 7 genes, copy number 5–6: AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1.
- chr3:183,447,608–183,884,889, 13 genes, copy number 5–6 (within-gene range 3–6): LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1, KLHL24, YEATS2, YEATS2-AS1, AC131160.1.
- chr3:183,829,271–184,039,369, 8 genes, copy number 6: PARL, RPSAP31, MIR4448, CYP2AB1P, ABCC5, ABCC5-AS1, EEF1A1P8, HTR3D.
- chr3:185,190,624–185,489,094, 5 genes, copy number 6 (within-gene range 4–6): EHHADH, EIF2S2P2, MIR5588, MAP3K13, RPL4P4.
- chr3:185,582,496–186,457,299, 12 genes, copy number 5 (within-gene range 4–5): SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ, TRA2B, NMRAL2P, ETV5, Metazoa_SRP, ETV5-AS1, DGKG, LINC02020.
- chr3:186,538,441–190,716,399, 75 genes, copy number 5–7 (within-gene range 5–8) (broad region; genes not listed).
- chr3:191,199,241–191,591,097, 6 genes, copy number 5: OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2.
- chr3:191,952,349–192,917,856, 11 genes, copy number 5 (within-gene range 5–6): AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2.
- chr8:143,368,876–143,549,729, 8 genes, copy number 5: RHPN1, AC105118.1, MAFA-AS1, MAFA, ZC3H3, AC067930.9, AC067930.3, RN7SKP175.
- chr8:143,566,192–143,583,304, 5 genes, copy number 7–14 (within-gene range 2–14): MROH6, AC067930.4, NAPRT, AC067930.5, AC067930.1.
- chr8:143,716,340–144,012,772, 19 genes, copy number 5 (within-gene range 3–5): MAPK15, AC105219.1, FAM83H, MIR4664, IQANK1, AC105219.3, SCRIB, MIR937, PUF60, AC234917.3, AC234917.1, NRBP2, MIR6845, AC234917.2, EPPK1, PLEC, MIR661, PARP10, GRINA.
- chr8:144,049,079–144,108,124, 10 genes, copy number 5–8 (within-gene range 2–8): SMPD5, OPLAH, MIR6846, AC109322.1, EXOSC4, MIR6847, GPAA1, CYC1, SHARPIN, MAF1.
- chr14:105,472,962–105,492,267, 3 genes, copy number 5 (within-gene range 3–5): CRIP2, CRIP1, AL928654.3.
- chr15:85,619,623–85,670,948, 3 genes, copy number 5 (within-gene range 2–5): AC087286.2, AC087286.1, RNU6-1280P.
- chr22:50,170,731–50,307,646, 12 genes, copy number 5: PANX2, TRABD, AL022328.3, AL022328.4, SELENOO, AL022328.1, AL022328.2, TUBGCP6, HDAC10, MAPK12, MAPK11, PLXNB2.

Autosomal genes at a single copy (total copy number 1): 6,991. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
